Somatic mutation profile of tumor specimen MP2PRT-PASSXJ-TBP1-A (aliquot MP2PRT-PASSXJ-TBP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASSXJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,329 days).
Specimen MP2PRT-PASSXJ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3135099-0e20-4eab-9f90-3368675aea2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASSXJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASSXJ-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cd9a05a-926f-4e95-a151-b3bcd66b6f76

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS9 | c.2966G>A p.R989H | Missense Mutation (SNP) | VAF 83/392 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs143377669; called by muse, mutect2, varscan2
- MUC16 | c.17237C>T p.T5746I | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as rs1424877011; called by mutect2, varscan2
- SEC14L3 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 83/463 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs369572715; called by muse, mutect2, varscan2
- THRA | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 36/469 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as rs773327077, COSV52846756; called by muse, mutect2
- ZNF704 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100589296; called by muse, mutect2, varscan2
- APOL1 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, varscan2
- IGKV4-1 | chr2:88886139 TATTATAGTACTCCTCCCACAGTGCTTCA>C | Missense Mutation (DEL) | VAF 41/202 reads (20%) | called by pindel, varscan2*
- ARFGEF3 | c.6243C>T p.S2081= | Silent (SNP) | VAF 62/471 reads (13%) | catalogued as COSV52470469; called by muse, mutect2, varscan2
